Somatic mutation profile of tumor specimen TCGA-QU-A6IN-01A (aliquot TCGA-QU-A6IN-01A-11D-A31L-08) from TCGA case TCGA-QU-A6IN, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.0 years (22,286 days).
Specimen TCGA-QU-A6IN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58405a78-8945-4c18-9765-7ed604ceaad5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QU-A6IN-10A (Blood Derived Normal), aliquot TCGA-QU-A6IN-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07fba38f-1992-42be-b6c7-a5fc5540d148

The open-access MAF lists 27 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 10, Nonsense Mutation 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51644190, COSV51644993, COSV51646200; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATOH1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1425612157, COSV100024493, COSV60038548; called by muse, mutect2, varscan2
- COL11A1 | c.2078A>T p.Q693L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV62192816; called by muse, mutect2, varscan2
- HTR1E | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777168858, COSV59510113; called by muse, mutect2, varscan2
- MAGEB6 | c.816T>A p.S272R | Missense Mutation (SNP) | VAF 53/64 reads (83%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.863); catalogued as COSV66872848; called by muse, mutect2, varscan2
- MRO | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199725891, COSV56497880; called by muse, mutect2
- PRICKLE1 | c.589A>G p.I197V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV61545809; called by muse, mutect2, varscan2
- PTCHD3 | c.1484T>C p.I495T | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as rs1423457092, COSV71257205; called by muse, mutect2, varscan2
- SZT2 | c.9293T>A p.L3098* (on ENST00000634258 / NM_001365999.1; = p.L3041* on NM_015284.4) | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as COSV65095244; called by muse, mutect2, varscan2
- THSD4 | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.686); catalogued as rs780681679, COSV55967152; called by muse, mutect2, varscan2
- TLR10 | c.1043C>T p.T348M | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs200661388; called by muse, mutect2, varscan2
- USP8 | c.2719G>T p.A907S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.513); catalogued as COSV56167327; called by muse, mutect2, varscan2
- WLS | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs755325364, COSV52045295, COSV99259957; called by muse, mutect2, varscan2
- ZNF408 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs750447937, COSV61239021; called by muse, mutect2, varscan2
- AFDN | c.1710_1744del p.M571Rfs*16 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel
- AMER3 | c.2121G>A p.G707= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV58469152; called by muse, mutect2, varscan2
- BPTF | c.3942C>T p.D1314= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV58844324; called by muse, mutect2, varscan2
- EFCC1 | c.1726T>C p.L576= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV71402119; called by muse, mutect2
- EPB41L3 | c.1476G>A p.T492= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV59450676; called by muse, mutect2, varscan2
- HLCS | c.6A>G p.E2= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as COSV60796983; called by muse, mutect2, varscan2
- MED24 | c.1818T>G p.T606= | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as COSV62420288; called by muse, mutect2, varscan2
- NCF4 | c.303C>T p.I101= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs746977479, COSV50620367; called by muse, mutect2, varscan2
- PRPF19 | c.1458C>T p.H486= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs751325779, COSV57127199; called by muse, mutect2, varscan2
- SLC5A10 | c.1494C>T p.C498= (on ENST00000395645 / NM_001042450.4; = p.C514= on NM_152351.5) | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs1246511024, COSV52413539; called by muse, mutect2, varscan2
- UHRF2 | c.2247C>T p.F749= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV52795559; called by muse, varscan2
- EPB41L3 | chr18:5630621 G>T | 5'Flank (SNP) | VAF 12/25 reads (48%) | catalogued as rs781075121; called by muse, mutect2, varscan2
